PECGS case C083-000079 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectosigmoid junction.
https://portal.gdc.cancer.gov/cases/f9de5d76-98ff-40e0-8be9-a9a9f4af6ad6

Demographics
Sex at birth: male; Age at index: 60 years; Year of birth: 1959; Education level: Some High School or Less.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Age at diagnosis: 60.4 years (22,061 days); AJCC pathologic stage: Stage IIA; Progression or recurrence: no.

Other clinical attributes
- BMI: 35.9.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 26.25; Alcohol history: No.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample C083-000079_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000079_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
